Somatic mutation profile of tumor specimen TCGA-55-6980-01A (aliquot TCGA-55-6980-01A-11D-1945-08) from TCGA case TCGA-55-6980, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-55-6980-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90f9b25b-9148-45a6-831d-ef73be8653d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6980-11A (Solid Tissue Normal), aliquot TCGA-55-6980-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df9d3002-d7e2-4134-9fe0-622601e81127

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2127_2129del p.E709_T710delinsD | In Frame Del (DEL) | VAF 18/72 reads (25%) | hotspot (GDC flag); catalogued as rs397517086, COSV51779132; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BCL10 | c.629A>C p.E210A | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV65353679; called by muse, mutect2
- CD8B | c.235A>C p.T79P | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV58925538; called by muse, mutect2, varscan2
- CYYR1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); catalogued as COSV54830136; called by muse, mutect2, varscan2
- MUL1 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs750565337, COSV51641366; called by muse, mutect2, varscan2
- SYNE2 | c.8764A>G p.I2922V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1212574097, COSV59946002; called by muse, mutect2, varscan2
- WNK1 | c.3995C>T p.T1332I (on ENST00000315939 / NM_018979.4; = p.T1085I on NM_014823.3) | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1157323165, COSV60029561; called by muse, mutect2, varscan2
- ZNF780A | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV61815038; called by muse, varscan2
- TP53 | c.412_427del p.A138Cfs*27 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel
- PLA2R1 | c.1758G>A p.T586= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs1323447241, COSV51776953, COSV51781887; called by muse, mutect2
- PLXNB2 | c.2613G>A p.G871= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs766649967, COSV63780840; called by mutect2, varscan2
- YBX2 | c.948C>T p.P316= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV50300656; called by muse, mutect2, varscan2
- ZAN | c.7992C>T p.G2664= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1006822979, COSV61807445; called by muse, mutect2, varscan2
